Surgical pathology report (de-identified scan), TCGA case TCGA-06-0648, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-0648-01A (Primary Tumor).

[page 1 of 2]
Surgical Pathology Report

TCGA-06-0648

CLINICAL HISTORY

The patient is a [REDACTED] with a left temporal lobe tumor.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, left temporal tumor, excisional biopsy: glioblastoma (WHO grade IV).

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

Results-Comments

Testing was done on block labeled

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

[page 2 of 2]
=====

INTRA-OPERATIVE CONSULTATION

A. Brain, excision biopsy: high-grade glioma.

[REDACTED]

GROSS DESCRIPTION

Received fresh from the operating room are multiple pieces of soft tan tissue, approximately 1.4 x 1.0 x 0.5 cm in aggregate. A sample of the tissue is used for frozen section. The frozen section residual is submitted in A1 and the unfrozen tissue is submitted in A2.

[REDACTED]

MICROSCOPIC DESCRIPTION

H stained sections show a pleomorphic glial neoplasm demonstrating frequent mitoses, vascular proliferation and pseudopalisading necrosis. Immunohistochemical stains show that approximately 3% of tumor nuclei react strongly with p53. The MIB-1 labeling index is approximately 20%.

ICD-9(s):

239.6 239.6

[REDACTED]

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
MGMT x 1	2	[REDACTED]	
MIB1-DA x 1	2	[REDACTED]	
P53DO7 x 1	2	[REDACTED]	
Rct 1 H/E x 1	2	[REDACTED]	
FS H/E x 1	(none)	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file e0191a13-f1b7-4279-8d2b-daa8b2f6d468 (TCGA-06-0648.8868018A-2FC1-482A-BA46-29245BEBA686.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).